Somatic mutation profile of tumor specimen 0DF0B5 from CCDI case PBBPMB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 24.0 years (8,772 days).
Specimen 0DF0B5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffcc0574-4744-4157-9b90-3a9fd9ea4f9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF0B6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90f4efc5-e424-4ba7-9854-3bc111e4d0bd

The open-access MAF lists 80 somatic variants for this specimen: 56 protein-altering or splice-affecting, 10 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, Frame Shift Del 6, 5'UTR 5, Intron 5, Nonsense Mutation 4, 3'UTR 3, Frame Shift Ins 3, Splice Site 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 332/674 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777621, CM144535, CM162083, COSV54223211, COSV54225487, COSV54226876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 240/581 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs137854535, CM983317; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.12406C>T p.Q4136* | Nonsense Mutation (SNP) | VAF 84/480 reads (18%) | catalogued as rs398123711; ClinVar: pathogenic; called by muse, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 34/878 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by muse, mutect2
- ANKUB1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 245/575 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753498617, COSV67167158; called by muse, mutect2, varscan2
- BX276092.9 | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs969679021, COSV70724288; called by muse, mutect2
- EZH2 | c.1715C>T p.P572L (on ENST00000460911 / NM_001203247.2; = p.P577L on NM_004456.5) | Missense Mutation (SNP) | VAF 307/696 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1554486390, COSV57449917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI2 | c.2629G>A p.A877T (on ENST00000361492 / NM_001374353.1; = p.A894T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/272 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58043812; called by muse, mutect2, varscan2
- HEPHL1 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 281/623 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59895309; called by muse, mutect2, varscan2
- HSPBP1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 351/755 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs1486506829; called by muse, mutect2, varscan2
- LRRIQ4 | c.1627G>C p.D543H | Missense Mutation (SNP) | VAF 438/931 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs1448677852, COSV52979418; called by muse, mutect2, varscan2
- NOMO1 | c.3154C>T p.R1052W | Missense Mutation (SNP) | VAF 172/501 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761500267; called by muse, mutect2, varscan2
- NOS3 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 351/746 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as rs145168353; called by muse, mutect2, varscan2
- PKD1 | c.12447C>A p.F4149L (on ENST00000262304 / NM_001009944.3; = p.F4148L on NM_000296.4) | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99238081; called by muse, mutect2, varscan2
- TRHDE | c.2788C>G p.P930A | Missense Mutation (SNP) | VAF 441/988 reads (45%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs201804594; called by muse, mutect2, varscan2
- WEE2 | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 255/581 reads (44%) | catalogued as rs1198846824; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2450G>C p.R817P | Missense Mutation (SNP) | VAF 296/749 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AOAH | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 196/400 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC2 | c.2116dup p.A706Gfs*50 | Frame Shift Ins (INS) | VAF 294/598 reads (49%) | called by mutect2, varscan2*
- BCAS1 | c.1311del p.S437Rfs*7 | Frame Shift Del (DEL) | VAF 372/812 reads (46%) | called by mutect2, varscan2
- CCDC88A | c.2362G>T p.D788Y | Missense Mutation (SNP) | VAF 308/1224 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CDH23 | c.20C>G p.T7S | Missense Mutation (SNP) | VAF 303/645 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDX2 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 166/314 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CENPM | c.310+1G>A p.X104_splice | Splice Site (SNP) | VAF 311/661 reads (47%) | called by muse, mutect2, varscan2
- CLYBL | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 617/1349 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- COL7A1 | c.5094G>C p.E1698D | Missense Mutation (SNP) | VAF 294/715 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- EZH2 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 438/1003 reads (44%) | called by muse, mutect2, varscan2
- FAM91A1 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 72/1486 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.048); called by muse, mutect2
- FASTK | c.870del p.L292Wfs*28 | Frame Shift Del (DEL) | VAF 282/626 reads (45%) | called by mutect2, varscan2
- FASTKD3 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 381/833 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- FKBP15 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 335/748 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FNDC1 | c.5383T>C p.F1795L | Missense Mutation (SNP) | VAF 449/1027 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRG2C | c.842C>G p.A281G | Missense Mutation (SNP) | VAF 218/1373 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.567); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 54/1446 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- LHX1 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 307/684 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- LRRC15 | c.225del p.N75Kfs*8 | Frame Shift Del (DEL) | VAF 318/682 reads (47%) | called by mutect2, varscan2
- MAGT1 | c.685G>T p.A229S (on ENST00000618282 / NM_001367916.1; = p.A261S on NM_032121.5) | Missense Mutation (SNP) | VAF 171/354 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- NFIX | c.268_269insGCTTTCCGCGAGG p.D90Gfs*33 | Frame Shift Ins (INS) | VAF 142/438 reads (32%) | called by mutect2, varscan2
- OR8K5 | c.445T>C p.Y149H | Missense Mutation (SNP) | VAF 66/808 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- RALGAPA1 | c.5764A>G p.I1922V | Missense Mutation (SNP) | VAF 141/629 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RBCK1 | c.397G>A p.A133T (on ENST00000356286 / NM_031229.4; = p.A91T on NM_006462.6) | Missense Mutation (SNP) | VAF 274/604 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RGL2 | c.1401_1404del p.E469Cfs*29 | Frame Shift Del (DEL) | VAF 182/472 reads (39%) | called by mutect2, varscan2
- RIN2 | c.1168_1178del p.N390Efs*58 (on ENST00000255006 / NM_001242581.1; = p.N341Efs*58 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 263/725 reads (36%) | called by mutect2, varscan2
- SCAF1 | c.1225C>A p.L409I | Missense Mutation (SNP) | VAF 173/370 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- SDCCAG8 | c.58A>T p.S20C | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLAMF7 | c.707T>A p.L236H | Missense Mutation (SNP) | VAF 360/857 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SMARCAD1 | c.3018A>G p.E1006= | Splice Region (SNP) | VAF 265/634 reads (42%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.3019G>T p.G1007C | Missense Mutation (SNP) | VAF 259/624 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- STON2 | c.1967T>A p.I656N (on ENST00000649389 / NM_001366849.2; = p.I599N on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 246/513 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SYNGAP1 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 209/448 reads (47%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TRAF3 | c.120_133del p.E41Dfs*9 | Frame Shift Del (DEL) | VAF 376/914 reads (41%) | called by mutect2, varscan2
- UTP20 | c.3867_3868insCAGGATATCACATTCTGGGTGCCCAGGCTTCTGTTTAGCCAGCAAA p.E1290Qfs*52 | Frame Shift Ins (INS) | VAF 15/493 reads (3%) | called by muse*, mutect2, varscan2*
- VEZF1 | c.792+2_792+5del p.X264_splice | Splice Site (DEL) | VAF 676/708 reads (95%) | called by mutect2, varscan2
- XPO1 | c.2383G>T p.A795S | Missense Mutation (SNP) | VAF 349/812 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- YY1AP1 | c.529C>T p.Q177* (on ENST00000295566 / NM_139118.2; = p.Q100* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 259/586 reads (44%) | called by muse, mutect2, varscan2
- ATP10A | c.3402C>G p.P1134= | Silent (SNP) | VAF 373/676 reads (55%) | catalogued as rs145087173; called by muse, mutect2, varscan2
- GAREM2 | c.1269G>A p.P423= | Silent (SNP) | VAF 443/1070 reads (41%) | called by muse, mutect2
- GPR84 | c.825A>G p.G275= | Silent (SNP) | VAF 31/634 reads (5%) | called by muse, mutect2
- ITGA11 | c.2466G>C p.L822= | Silent (SNP) | VAF 251/571 reads (44%) | called by muse, mutect2, varscan2
- LIPF | c.1050T>C p.D350= | Silent (SNP) | VAF 74/863 reads (9%) | called by muse, mutect2
- OR1C1 | c.399C>T p.T133= | Silent (SNP) | VAF 310/744 reads (42%) | catalogued as rs758965164, COSV68715325; called by muse, mutect2, varscan2
- RPS6KA6 | c.1119C>T p.P373= | Silent (SNP) | VAF 332/352 reads (94%) | catalogued as rs55837425; called by muse, mutect2, varscan2
- SRRM4 | c.1620C>T p.S540= | Silent (SNP) | VAF 358/816 reads (44%) | catalogued as rs560707252; called by muse, mutect2, varscan2
- WASHC4 | c.2613A>G p.R871= | Silent (SNP) | VAF 253/592 reads (43%) | catalogued as rs370839435; called by muse, mutect2, varscan2
- YTHDF2 | c.963A>G p.S321= | Silent (SNP) | VAF 197/540 reads (36%) | called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 6/122 reads (5%) | catalogued as rs1262556378; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 40/972 reads (4%) | called by muse, mutect2
- DMXL2 | c.7923+72C>T | Intron (SNP) | VAF 75/141 reads (53%) | called by muse, mutect2, varscan2
- DUSP13 | c.*355G>A | 3'UTR (SNP) | VAF 228/516 reads (44%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 28/307 reads (9%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
- MYOF | c.-88C>G | 5'UTR (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- SCP2 | c.-25G>A | 5'UTR (SNP) | VAF 231/364 reads (63%) | catalogued as rs750884412; called by muse, mutect2, varscan2
- SCP2 | c.-24C>G | 5'UTR (SNP) | VAF 238/374 reads (64%) | called by muse, mutect2, varscan2
- SLC25A3 | c.282+186T>A | Intron (SNP) | VAF 238/497 reads (48%) | called by muse, mutect2, varscan2
- SLC27A4 | c.*27G>A | 3'UTR (SNP) | VAF 122/251 reads (49%) | catalogued as rs754017632; called by muse, mutect2, varscan2
- SLC3A1 | c.-3G>T | 5'UTR (SNP) | VAF 194/345 reads (56%) | catalogued as rs1255450107; called by muse, mutect2, varscan2
- TASOR | c.4301-90C>T | Intron (SNP) | VAF 74/154 reads (48%) | catalogued as rs752687213; called by muse, mutect2, varscan2
- TSSK6 | c.-16C>T | 5'UTR (SNP) | VAF 375/798 reads (47%) | called by muse, mutect2, varscan2
